Gene-level copy-number profile of tumor specimen C3N-02155-03 from CPTAC case C3N-02155, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 45.4 years (16,568 days).
Specimen C3N-02155-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 040bfadd-8b7d-4f64-8f18-ac74ba7541c7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02155-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/78963d85-9f9c-487c-a46e-b91558800455

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 1,967; copy number 2: 16,152; copy number 3: 21,608; copy number 4: 9,801; copy number 5: 3,173; copy number 6: 2,282; copy number 7: 2,142; copy number 8: 1,092; copy number 9: 146; copy number 10: 74; copy number 11: 56; copy number 12: 104; copy number 13: 123; copy number 14: 42; copy number 15: 13; copy number 18: 9; copy number 19: 19; copy number 21: 11; copy number 22: 40.

Homozygous deletions (total copy number 0; autosomes only): 33 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr6:29,896,654–29,929,232, 5 genes: HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr9:64,462,819–64,498,745, 6 genes: CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1.
- chr10:106,970,021–110,008,381, 18 genes (within-gene range 0–2): RNA5SP325, RNA5SP326, LINC01435, PTGES3P5, AL353740.1, LINC02661, MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P, PHB2P1, BTF3P15, AL390123.1, XIAPP1, RPL21P91, XPNPEP1, RNU4-5P, ADD3-AS1.
- chr10:111,498,191–111,498,941, 1 gene: RPS6P15.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,871 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,874,793–218,444,619, 1,814 genes, copy number 7 (broad region; genes not listed).
- chr1:241,590,102–248,937,043, 206 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr4:138,164,097–138,663,403, 5 genes, copy number 7 (within-gene range 4–8): SLC7A11, AC093903.1, LINC00498, LINC00499, LINC00500.
- chr6:18,128,311–18,307,079, 6 genes, copy number 7: TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P.
- chr7:37,032–62,275,678, 1,035 genes, copy number 8 (broad region; genes not listed).
- chr14:19,124,807–20,641,691, 98 genes, copy number 7–22 (broad region; genes not listed).
- chr14:24,265,538–27,845,286, 46 genes, copy number 8–13 (within-gene range 6–20): RABGGTA, AL096870.12, AL096870.10, DHRS1, NOP9, CIDEB, LTB4R2, LTB4R, ADCY4, AL096870.1, RIPK3, NFATC4, NYNRIN, CBLN3, KHNYN, SDR39U1, AL132800.1, CMA1, CTSG, AL136018.1, GZMH, GZMB, STXBP6, AL161663.2, AL161663.1, LINC02286, HMGN2P6, OR7K1P, AL079352.1, LINC02306, AL359396.1, AL359396.2, AL132633.1, CYB5AP5, NOVA1, AL079343.1, LINC02588, AL110292.1, LINC02294, LINC02293, AL132718.1, MIR4307HG, MIR4307, AL390334.1, LINC00645, MIR3171.
- chr14:32,006,902–39,388,513, 133 genes, copy number 8–21 (within-gene range 6–21) (broad region; genes not listed).
- chr14:58,646,631–59,184,247, 1 gene, copy number 11 (within-gene range 6–11): LINC01500.
- chr14:59,135,488–60,515,543, 25 genes, copy number 11 (within-gene range 6–11): AKR1B1P5, PPIAP5, DAAM1, GPR135, L3HYPDH, AL121694.1, JKAMP, CCDC175, RTN1, MIR5586, AL133299.1, LRRC9, AL157911.1, PCNX4, DHRS7, SCOCP1, PSMA3P1, RPL17P2, AL157756.1, PPM1A, LINC02322, C14orf39, RBM8B, GNRHR2P1, SALL4P7.
- chr14:64,914,485–65,061,803, 1 gene, copy number 11 (within-gene range 6–11): CHURC1-FNTB.
- chr14:64,945,814–66,509,394, 29 genes, copy number 11–14 (within-gene range 6–14): RAB15, FNTB, AL139022.2, MAX, MIR4706, AL139022.1, RNU2-14P, LINC02324, AL355076.3, AL355076.2, RPL21P7, AL355076.1, PTBP1P, MIR4708, FUT8, FUT8-AS1, RPL21P8, MIR625, EIF1AXP2, NCOA4P1, FTH1P13, AL391261.1, AL391261.2, YBX1P1, LINC02290, Y_RNA, AL359232.1, AL157997.1, CCDC196.
- chr14:67,610,986–71,741,229, 106 genes, copy number 13 (broad region; genes not listed).
- chr14:77,024,543–77,769,742, 34 genes, copy number 7: IRF2BPL, AC007686.3, LINC02288, AC007686.2, LINC02289, AC007686.5, CIPC, AC007375.2, TMEM63C, ZDHHC22, AC007375.3, FAM204DP, AC007375.1, NGB, MIR1260A, POMT2, GSTZ1, TMED8, AC007954.1, SAMD15, NOXRED1, VIPAS39, AHSA1, AF111168.1, ISM2, SPTLC2, RN7SL587P, COX6CP11, ALKBH1, RPL21P10, ZMYND19P1, SLIRP, SNW1, C14orf178.
- chr14:88,819,608–89,954,777, 21 genes, copy number 8–12: AL121768.1, RNU4-92P, TTC8, Y_RNA, MPPE1P1, FOXN3, AL138478.1, CAP2P1, AL357093.2, AL357093.1, AL356805.1, AL137230.2, FOXN3-AS1, FOXN3-AS2, RN7SKP107, AL137230.1, Y_RNA, RN7SKP255, CHORDC2P, EFCAB11, RAB42P1.
- chr14:94,280,460–95,050,957, 22 genes, copy number 11–13: SERPINA10, SERPINA6, SERPINA2, SERPINA1, AL132708.1, SERPINA11, SERPINA9, SERPINA12, SERPINA4, SERPINA5, AL049839.2, AL049839.3, SERPINA3, ADIPOR1P2, SERPINA13P, AL049839.1, RPSAP4, GSC, RPL15P2, AL121612.1, LINC02279, AL390254.1.
- chr14:97,924,637–99,332,015, 15 genes, copy number 7: LINC01550, AL163932.1, LINC02295, RN7SL714P, AL132719.1, C14orf177, AL132796.1, AL132796.3, AL132796.2, RPL3P4, AL162151.2, AL162151.1, BCL11B, AL109767.1, AL132819.1.
- chr14:104,753,147–106,879,812, 235 genes, copy number 8–14 (broad region; genes not listed).
- chr20:51,782,331–54,269,542, 37 genes, copy number 7–9: SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.
- chr21:36,005,338–36,016,546, 2 genes, copy number 7: LINC01436, RPL23AP3.

Autosomal genes at a single copy (total copy number 1): 1,534. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
